Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3ZM, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3ZM-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

DOB:
Physician:

Collected:

Received:

Case type: Surgical Case

Accession:

DIAGNOSIS

(A) RIGHT FACIAL LYMPH NODE:

One lymph node, negative for tumor (0/1).

(B) TUMOR, CAROTID SHEATH:

PAPILLARY THYROID CARCINOMA.

(C) POST-TRACHEAL WALL MASS:

PAPILLARY THYROID CARCINOMA.

(D) TOTAL THYROIDECTOMY AND RIGHT NECK DISSECTION

PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Right lobe and isthmus

Multi-focal: No

Size = 5.7 cm

Extrathyroidal extension: Present, extending into soft tissue and skeletal muscle

Lymphovascular invasion: Absent

Resection Margins: Positive

Lymph nodes:

METASTATIC PAPILLARY THYROID CARCINOMA IN 7 OF 26 LYMPH NODES

Location: Right, neck

Extracapsular extension: Absent

ICD-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

AW
6/17/12

GROSS DESCRIPTION

(A) RIGHT FACIAL LYMPH NODE - Received is a 1.9 x 1.2 x 0.6 cm portion of yellow-tan fibrofatty adipose tissue. Specimen is dissected revealing a 0.8 x 0.6 x 0.5 cm possible lymph node. Possible lymph node is trisected and submitted entirely in cassette A.

(B) TUMOR, CAROTID SHEATH - Two fragments of pink soft tissue (0.8 x 0.6 x 0.2 cm and 0.5 x 0.1 x 0.1 cm) are received and entirely submitted for frozen section B.

*FS/DX: PAPILLARY THYROID CARCINOMA.

(C) POST TRACHEAL WALL MASS - Received is a rubbery to somewhat firm, unoriented fragment of muscular tissue admixed with scanty amount of adipose tissue measuring 2.8 x 2.0 x 1.5 cm. Cut surface of the tissue is mahogany brown, glistening. Entirely submitted.

SECTION CODE: C1-C3, entire tissue.

(D) TOTAL THYROIDECTOMY AND RIGHT NECK DISSECTION CONTENTS - An en bloc resection including thyroid (left lobe 6.1 x 3.2 x 2.7 cm, isthmus 3.2 x 2.7 x 2.2 cm), anterior full thickness strap muscles, and anterior adipose tissue (9.4 x 6.6 x 3.5 cm including right thyroid). A possible left lower parathyroid (0.5 cm in diameter) is located at the left lateral posterior inferior aspect of the thyroid. A portion of ossified cartilage (1.4 x 0.5 x 0.2 cm) is located at the posterior aspect of the right lobe.

[page 2 of 2]
Surgical Pathology Report

DOB:
Physician:

Collected: Pathologist:
Received: Case type: Surgical Case

Accession:

A firm, tan mass (5.7 x 4.1 x 3.9 cm) is located within the right lobe and isthmus and extends into perithyroidal adipose tissue and skeletal muscle anteriorly and posteriorly. The posterior aspect of the specimen is rough and fibrotic with gross involvement of tumor. The superior portion of tumor is surrounded by a dark brown hemorrhagic edge infiltrating into adipose tissue. The anterior soft tissue margin is widely free of tumor.

A cystic colloid-filled nodule (6.1 x 3.2 x 2.7 cm) is located in the middle and lower poles of the left lobe.

The remaining uninvolved thyroid parenchyma is beefy red and unremarkable. Twenty-three possible lymph nodes are identified within the right neck dissection and anterior adipose tissue. Tumor and normal tissue are submitted to the

INK CODE: Black – right posterior tissue edge for orientation.

SECTION CODE: D1, left lobe, representative unremarkable; D2, left inferior and middle lobe nodule and possible parathyroid gland; D3, left inferior and middle lobe nodule; D4, isthmus with tumor; D5, D6, tumor with isthmus into anterior soft tissue; D7-D14, superior portion of tumor with muscle and fat involving posterior tissue edge; D15, superior portion of right lobe tumor with muscle and fibroadipose tissue into posterior tissue edge and one possible lymph node; D16, right lobe tumor with fragment of ossified cartilage, decal; D17-D26, one possible lymph node per cassette, bisected, right neck dissection; D27-D34, one possible lymph node per cassette, serially sectioned, right neck dissection; D35, four possible lymph nodes, anterior soft tissue; D36, one possible lymph node, bisected, anterior soft tissue.

CLINICAL HISTORY

Papillary thyroid cancer.

SNOMED CODES

T-B6000, M-80503, T-C4200, M-80506,

"Some tests reported here may have been developed and performance characteristics determined by approved by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or

Entire report and diagnosis completed by:

Page 2 of 2	
Surgical Pathology Report	
File under: Pathology	

Source: NCI Genomic Data Commons file cf9848d8-77e1-44ef-b9f1-0dd5c2d82aaf (TCGA-EL-A3ZM.66FF897A-C66C-486F-B72F-D06F8F35B89D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).